Gene-level copy-number profile of tumor specimen TCGA-EJ-5499-01A from TCGA case TCGA-EJ-5499, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.0 years (22,286 days).
Specimen TCGA-EJ-5499-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.03cb6ce8-70a3-4eb2-9caf-a0617fe44842.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-5499-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/295fdd50-9a61-4d33-8cf1-2c3093da6264

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 4,941; copy number 2: 54,756; copy number 3: 86.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-5499-01A-01D-1574-01): tumor purity 0.47, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:63,774,017–64,181,498, 1 gene (within-gene range 0–1): ROR1.
- chr1:63,843,196–64,171,342, 4 genes (within-gene range 0–1): CFL1P3, RNU6-809P, Y_RNA, ROR1-AS1.
- chr1:64,384,398–64,693,058, 3 genes: RNU7-62P, CACHD1, MIR4794.
- chr10:87,607,985–87,863,533, 8 genes (within-gene range 0–1): AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr10:87,878,692–87,880,427, 1 gene: AC063965.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,574. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
